Somatic mutation profile of tumor specimen ALCH-B26Y-TTP1-A (aliquot ALCH-B26Y-TTP1-A-1-0-D-A76N-36) from ALCHEMIST case ALCH-B26Y, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 74.9 years (27,350 days).
Specimen ALCH-B26Y-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 410ced2a-3022-4e6b-bf23-a5f900a37964.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B26Y-NB1-A (Blood Derived Normal), aliquot ALCH-B26Y-NB1-A-1-0-D-A76N-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/07e1946c-e382-4c12-8e8f-0494cfe47ba6

The open-access MAF lists 17 somatic variants for this specimen: 7 protein-altering or splice-affecting, 7 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Silent 7, Missense Mutation 5, Intron 2, Frame Shift Del 1, In Frame Del 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.2237_2251del p.E746_T751delinsA | In Frame Del (DEL) | VAF 32/292 reads (11%) | hotspot (GDC flag); catalogued as rs121913425, COSV51766481, COSV51769364, COSV51779850, COSV51794924, COSV51856180, COSV51859776; ClinVar: drug response; called by mutect2, pindel
- DEPDC1 | c.853del p.D285Ifs*16 | Frame Shift Del (DEL) | VAF 7/66 reads (11%) | catalogued as COSV63958177; called by mutect2, pindel, varscan2
- FGFR3 | c.517C>T p.R173C | Missense Mutation (SNP) | VAF 10/125 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1031160906; called by muse, mutect2
- ISLR2 | c.137C>T p.P46L | Missense Mutation (SNP) | VAF 14/182 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62302227; called by muse, mutect2
- ABCB11 | c.1051G>A p.E351K | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT tolerated (0.22); PolyPhen benign (0.033); called by muse, mutect2
- ATP23 | c.305C>T p.S102L | Missense Mutation (SNP) | VAF 56/258 reads (22%) | SIFT tolerated (0.13); PolyPhen benign (0.089); called by muse, mutect2, varscan2
- LARGE1 | c.2014C>T p.R672W | Missense Mutation (SNP) | VAF 14/223 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.892); called by muse, mutect2
- DHX30 | c.1408C>T p.L470= (on ENST00000445061 / NM_138615.3; = p.L431= on NM_014966.3) | Silent (SNP) | VAF 10/178 reads (6%) | called by muse, mutect2
- GATA5 | c.789G>T p.V263= | Silent (SNP) | VAF 9/108 reads (8%) | called by muse, mutect2
- GBA | c.732C>T p.Y244= | Silent (SNP) | VAF 14/291 reads (5%) | catalogued as rs1423274387; called by muse, mutect2
- LRFN2 | c.591G>A p.Q197= | Silent (SNP) | VAF 8/208 reads (4%) | called by muse, mutect2
- MAGEB4 | c.684G>A p.G228= | Silent (SNP) | VAF 10/87 reads (11%) | called by muse, mutect2, varscan2
- MAGIX | c.366T>G p.G122= | Silent (SNP) | VAF 11/151 reads (7%) | called by muse, mutect2
- OSBPL7 | c.1173C>T p.T391= | Silent (SNP) | VAF 8/124 reads (6%) | called by muse, mutect2
- CCDC78 | c.1201-16T>C | Intron (SNP) | VAF 12/162 reads (7%) | catalogued as rs367959341; called by muse, mutect2
- CNOT2 | c.1241-16T>G | Intron (SNP) | VAF 22/169 reads (13%) | called by muse, mutect2, varscan2
- MARVELD3 | chr16:71640617 C>G | 3'Flank (SNP) | VAF 7/140 reads (5%) | called by muse, mutect2
